Somatic mutation profile of tumor specimen ALCH-B2SG-TTP1-A (aliquot ALCH-B2SG-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2SG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.7 years (28,012 days).
Specimen ALCH-B2SG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01a31e21-4f0a-47ee-8d1e-b7e7323cb511.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2SG-NB1-A (Blood Derived Normal), aliquot ALCH-B2SG-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e1637a5-af43-49e7-9303-54c585e0f184

The open-access MAF lists 84 somatic variants for this specimen: 48 protein-altering or splice-affecting, 24 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 24, Intron 5, Nonsense Mutation 5, 3'UTR 3, 5'UTR 2, 5'Flank 2, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 203/805 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.764_766del p.I255del | In Frame Del (DEL) | VAF 77/234 reads (33%) | hotspot (GDC flag); catalogued as rs1064794309; called by pindel, varscan2
- AC011448.1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1004284343, COSV52278353; called by muse, mutect2, varscan2
- COL4A2 | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866088460; called by muse, mutect2, varscan2
- DYNC1H1 | c.9847G>A p.D3283N | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV64140476; called by muse, mutect2
- ESPL1 | c.5807C>T p.S1936L | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.207); catalogued as rs763549148, COSV54475697; called by muse, mutect2
- F8 | c.2369C>A p.P790H | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as CD063520; called by muse, mutect2, varscan2
- FAM186B | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as rs373047444; called by muse, varscan2
- FKTN | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs753641411; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INTS4 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs774107778, COSV101417240; called by muse, mutect2, varscan2
- IRS4 | c.3634G>A p.A1212T | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV64533491, COSV64536522; called by mutect2, varscan2
- LAMB4 | c.4187G>C p.G1396A | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV52721777; called by muse, mutect2, varscan2
- MRTFA | c.474G>C p.Q158H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456009071; called by muse, mutect2
- PGGHG | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761569651; called by muse, mutect2, varscan2
- ROBO2 | c.4016G>A p.G1339E | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100164631, COSV59936475; called by muse, mutect2
- TPBG | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as rs1208162077; called by muse, varscan2
- ZNF292 | c.7614T>A p.N2538K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.057); catalogued as rs778061441; called by mutect2, varscan2
- BCAS4 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); called by muse, varscan2
- C1orf112 | c.2359T>A p.L787I | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.025); called by muse, varscan2
- CAMK1G | c.663A>C p.E221D | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CGN | c.3031T>C p.S1011P | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2
- CHD5 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNOT1 | c.4242G>C p.K1414N | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CRACD | c.3145C>G p.Q1049E | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- DCAF12L2 | c.455T>G p.I152S | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DCLK3 | c.606C>A p.S202R | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); called by mutect2, varscan2
- DOCK6 | c.2083C>A p.P695T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM161B | c.1174G>A p.A392T (on ENST00000651776; = p.A329T on NM_152445.3) | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- FAM186B | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- FAM186B | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- FAM186B | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- FAM186B | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | called by muse, varscan2
- FAM186B | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 26/168 reads (15%) | called by muse, varscan2
- FGG | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HDLBP | c.3372_3373insA p.E1125Rfs*6 | Frame Shift Ins (INS) | VAF 83/357 reads (23%) | called by mutect2, pindel, varscan2
- MAGEA6 | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 13/411 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- NEK6 | c.293del p.K98Sfs*3 | Frame Shift Del (DEL) | VAF 23/167 reads (14%) | called by mutect2, pindel, varscan2
- NEUROD4 | c.10A>C p.T4P | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); called by mutect2, varscan2
- OCLN | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR1F1 | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- OSER1 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PCDH19 | c.2749A>T p.S917C (on ENST00000373034 / NM_001184880.2; = p.S869C on NM_020766.3) | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PHACTR3 | c.1329-7T>G | Splice Region (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2
- PI4KB | c.1082A>G p.H361R (on ENST00000368873 / NM_001369623.1; = p.H373R on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/470 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SLFN11 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- SNRNP200 | c.6001G>A p.D2001N | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.014); called by muse, mutect2
- TBC1D16 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF45 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 42/340 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ANK2 | c.11556C>T p.A3852= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as rs751064768, COSV52156461; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGEF6 | c.681A>G p.K227= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- BID | c.264C>T p.H88= (on ENST00000317361 / NM_197966.2; = p.H42= on NM_001196.4) | Silent (SNP) | VAF 32/608 reads (5%) | catalogued as rs150608132; called by muse, mutect2
- BPTF | c.7851A>C p.T2617= | Silent (SNP) | VAF 71/514 reads (14%) | called by muse, mutect2, varscan2
- CDKL3 | c.843G>A p.L281= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- CFAP43 | c.4416G>A p.L1472= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- ENTPD3 | c.1494C>G p.A498= | Silent (SNP) | VAF 53/338 reads (16%) | called by muse, mutect2, varscan2
- FAM186B | c.2199C>T p.I733= | Silent (SNP) | VAF 44/230 reads (19%) | called by muse, varscan2
- FAM186B | c.2004C>G p.A668= | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- FAM186B | c.1014C>T p.S338= | Silent (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- FAM186B | c.690C>T p.V230= | Silent (SNP) | VAF 24/122 reads (20%) | called by muse, varscan2
- GABRA1 | c.1161C>T p.A387= | Silent (SNP) | VAF 22/218 reads (10%) | called by muse, mutect2
- IBA57 | c.795G>A p.L265= | Silent (SNP) | VAF 46/670 reads (7%) | called by muse, mutect2
- KMT2B | c.6879C>T p.P2293= | Silent (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- MINK1 | c.3507G>C p.L1169= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs748793626; called by muse, mutect2
- MYF6 | c.573C>T p.S191= | Silent (SNP) | VAF 22/500 reads (4%) | called by muse, mutect2
- NALCN | c.763A>C p.R255= | Silent (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- OLFML1 | c.336C>A p.I112= | Silent (SNP) | VAF 21/215 reads (10%) | called by muse, mutect2, varscan2
- PEAK1 | c.987A>T p.G329= | Silent (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- RET | c.1920C>G p.A640= | Silent (SNP) | VAF 70/962 reads (7%) | called by muse, mutect2
- SOS2 | c.1515T>G p.T505= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- SPTB | c.3510C>T p.F1170= | Silent (SNP) | VAF 15/359 reads (4%) | called by muse, mutect2
- TNXB | c.9063C>T p.D3021= (on ENST00000647633; = p.D2774= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/710 reads (8%) | catalogued as rs776364224, COSV64486365; called by muse, mutect2
- TPBG | c.688C>T p.L230= | Silent (SNP) | VAF 46/158 reads (29%) | catalogued as rs187936619, COSV63882491; called by muse, varscan2
- BAZ1A | chr14:34875450 del G | 5'Flank (DEL) | VAF 52/274 reads (19%) | called by mutect2, pindel, varscan2
- BCAS4 | c.*74G>C | 3'UTR (SNP) | VAF 20/160 reads (13%) | called by muse, varscan2
- C4orf50 | c.-222G>A | 5'UTR (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- CCDC18 | c.-3+437G>A | Intron (SNP) | VAF 29/460 reads (6%) | called by muse, mutect2
- CCL4L2 | c.*172G>C | 3'UTR (SNP) | VAF 24/505 reads (5%) | called by muse, mutect2
- CCN6 | c.590-1180C>A | Intron (SNP) | VAF 10/108 reads (9%) | catalogued as rs1282962863; called by muse, mutect2
- CYHR1 | chr8:144465070 C>T | 5'Flank (SNP) | VAF 44/147 reads (30%) | called by muse, varscan2
- DVL3 | c.600-37G>A | Intron (SNP) | VAF 42/148 reads (28%) | called by muse, mutect2, varscan2
- EFHC1 | c.723+223T>C | Intron (SNP) | VAF 16/175 reads (9%) | catalogued as rs1293471973; called by muse, mutect2
- GOLGA8N | c.-9C>G | 5'UTR (SNP) | VAF 113/1050 reads (11%) | called by muse, mutect2, varscan2
- HOOK3 | c.1621-1833A>G | Intron (SNP) | VAF 7/105 reads (7%) | catalogued as rs1371440928; called by muse, mutect2
- TMEM135 | c.*1210A>G | 3'UTR (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2
